Gene-level copy-number profile of tumor specimen MP2PRT-PAPDEU-TMP1-A from MP2PRT case MP2PRT-PAPDEU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.4 years (3,426 days).
Specimen MP2PRT-PAPDEU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c4b4e4f3-a191-4e4a-859d-717accd6d9c6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAPDEU-NM1-A (blood derived cancer - bone marrow, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,266 have no estimate.
https://portal.gdc.cancer.gov/files/72834174-f477-4cf6-9b3d-9054296cb70d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 184; copy number 1: 2,186; copy number 2: 54,887; copy number 3: 519; copy number 4: 5; copy number 5: 551; copy number 8: 25.

Homozygous deletions (total copy number 0; autosomes only): 184 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,078,010–89,085,787, 2 genes (within-gene range 0–1): IGKV2-14, IGKV3-15.
- chr2:89,170,775–89,254,015, 12 genes (within-gene range 0–1): IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32.
- chr6:26,196,784–26,234,987, 11 genes: H3C4, H2AC7, H2BC7, AL031777.1, H4C5, H2BC8, H2AC8, H3C5P, H3C6, H2AC9P, H1-3.
- chr7:38,239,580–38,378,804, 23 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2, TRGV1.
- chr7:142,656,701–142,802,748, 26 genes: TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBC2.
- chr14:22,438,547–22,511,024, 40 genes (within-gene range 0–1): TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36, TRAJ35, TRAJ34, TRAJ33, TRAJ32, TRAJ31.
- chr14:105,851,705–106,122,709, 52 genes (within-gene range 0–2): IGHM, MIR4539, MIR4507, MIR4538, MIR4537, IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1, ADAM6, AC246787.1, IGHV1-2, IGHVIII-2-1, IGHV1-3, IGHV4-4, IGHV7-4-1, IGHV2-5, IGHVIII-5-1, IGHVIII-5-2, IGHV3-6, IGHV3-7, IGHV3-64D, IGHV5-10-1, IGHV3-11, IGHVIII-11-1, IGHV1-12.
- chr14:106,170,749–106,171,052, 1 gene (within-gene range 0–1): IGHVIII-16-1.
- chr14:106,436,415–106,441,007, 2 genes (within-gene range 0–1): AC244452.1, IGHVII-40-1.
- chr14:106,584,718–106,593,347, 3 genes (within-gene range 0–2): IGHVII-51-2, IGHV3-52, IGHV3-53.
- chr14:106,675,017–106,704,286, 8 genes (within-gene range 0–2): IGHV3-66, IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68.
- chr15:25,848,747–25,848,825, 1 gene (within-gene range 0–1): MIR4715.
- chr15:89,950,760–89,951,345, 1 gene: AC027176.3.
- chr15:90,006,755–90,026,003, 2 genes (within-gene range 0–1): MIR3174, AC087284.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 576 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:55,746,639–55,993,746, 2 genes, copy number 5: AC009997.1, NEDD4.
- chr15:56,087,280–57,326,447, 26 genes, copy number 5: RFX7, AC084783.1, TEX9, AC068726.1, RNU6-1287P, HMGB1P33, AC084782.1, AC084782.2, MNS1, AC084782.3, AC090518.1, ZNF280D, Y_RNA, AC090517.4, AC090517.2, AC090517.3, AC090517.5, AC090517.1, AC010999.2, AC010999.1, TCF12, HNRNPA3P11, SNORD13D, LINC00926, LINC01413, NDUFB10P1.
- chr15:57,706,695–58,497,866, 3 genes, copy number 5 (within-gene range 3–5): POLR2M, AC090651.1, ALDH1A2.
- chr15:58,138,169–58,865,303, 27 genes, copy number 5 (within-gene range 3–5): AQP9, MTCO3P23, MTND3P12, AC066616.2, MTND5P32, MTCYBP23, AC066616.1, LIPC, LIPC-AS1, AC084781.1, AC084781.2, AC018904.2, AC018904.1, ADAM10, HMGB1P51, AC091046.1, HSP90AB4P, RN7SKP95, AC091046.2, AC090515.6, AC090515.3, SNORD3P1, AC090515.2, MINDY2, AC090515.5, AC090515.4, ZNF444P1.
- chr15:58,879,050–58,933,679, 2 genes, copy number 5 (within-gene range 3–5): SLTM, AC025918.1.
- chr15:62,060,503–62,884,034, 21 genes, copy number 5: AC104590.1, C2CD4A, NPM1P47, C2CD4B, AC126323.2, AC126323.1, AC126323.3, Metazoa_SRP, GOLGA2P11, AC126323.4, AC126323.6, AC126323.5, MIR8067, MIR6085, HMGN1P26, AC032011.1, TLN2, MGC15885, AC100839.1, MIR190A, AC103740.1.
- chr15:63,042,632–63,071,915, 3 genes, copy number 5: TPM1, TPM1-AS, AC079328.2.
- chr15:63,276,018–66,253,747, 86 genes, copy number 5 (broad region; genes not listed).
- chr21:13,038,160–13,705,518, 22 genes, copy number 8: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1, AJ239318.1, FGF7P2, ANKRD30BP1, MIR3156-3, GTF2IP2, VN1R8P, LINC01674, SNX19P1, OR4K11P, OR4K12P, POTED, RNU6-286P, MIR3118-1, AL050303.2, GRAMD4P1, CXADRP1, AL050303.3, LONRF2P5.
- chr21:13,905,960–13,906,488, 1 gene, copy number 5: SNX18P13.
- chr21:14,371,115–14,383,484, 1 gene, copy number 5: HSPA13.
- chr21:17,593,653–17,819,386, 7 genes, copy number 5: BTG3, BTG3-AS1, AP000432.1, AP000432.2, C21orf91-OT1, C21orf91, AL109761.1.
- chr21:32,733,899–33,931,607, 35 genes, copy number 5 (within-gene range 3–5): PAXBP1, C21orf62-AS1, AP000280.2, C21orf62, AP000281.1, SNORA70, AP000281.2, AP000282.1, LINC01690, OLIG2, LINC00945, OLIG1, AP000289.1, AP000290.1, LINC01548, IFNAR2, AP000295.1, IL10RB-DT, IL10RB, IFNAR1, USF1P1, IFNGR2, TMEM50B, RPS5P3, AP000302.1, DNAJC28, GART, BTF3P6, SON, MIR6501, DONSON, AP000311.1, CRYZL1, ITSN1, ATP5PO.
- chr21:33,918,995–33,919,338, 1 gene, copy number 5 (within-gene range 4–5): RN7SL740P.
- chr21:34,073,224–39,929,397, 133 genes, copy number 5 (broad region; genes not listed).
- chr21:41,141,493–46,605,208, 206 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,186. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
